CPTAC case C3N-00661 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d3936bbd-6aa7-4525-bd74-9d9d11cbb98a

Demographics
Sex at birth: male; Race: white; Year of birth: 1967; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 49.4 years (18,038 days); Year of diagnosis: 2016; Last known disease status: With tumor; Days to last known disease status: 1,107 days (3.0 years); Progression or recurrence: yes; Days to recurrence: 339 days; Days to last follow up: 1,107 days (3.0 years).
   Pathology details: Greatest tumor dimension: 7 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 484 days (1.3 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 698 days (1.9 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,107 days (3.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 370 days (1.0 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,107 days (3.0 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 105 kg; Height: 176 cm; BMI: 33.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2.3; Cigarettes per day: 5; Tobacco smoking onset year: 1987; Tobacco smoking quit year: 1996; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 9.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00661-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -12 days; Initial weight: 1,370 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00661-21: Section location: Temporal Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-00661-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 1,307 mg.
- Sample C3N-00661-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 1,323 mg.
- Sample C3N-00661-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 965 mg.
- Sample C3N-00661-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -12 days; Method of sample procurement: Blood Draw.
- Sample C3N-00661-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
